TCGA case TCGA-23-1030 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Cedars Sinai. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cbcf6922-a3c0-43a1-826e-642918b0a635

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 64 years; Vital status: Alive.

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 64.1 years (23,416 days); Year of diagnosis: 2006; Method of diagnosis: Surgical Resection; FIGO stage: Stage IIIC; Tumor grade: G3; Prior treatment: No; Days to last follow up: 886 days (2.4 years).
   Pathology details: Lymphatic invasion present: Yes; Residual tumor measurement: 1-10 mm; Vascular invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 62 days; Days to treatment end: 165 days; Number of cycles: 6; Treatment dose: 5,010 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 62 days; Days to treatment end: 165 days; Number of cycles: 6; Treatment dose: 2,130 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel Poliglumex; Treatment intent type: Consolidation Therapy; Days to treatment start: 243 days; Days to treatment end: 438 days (1.2 years); Number of cycles: 8; Treatment dose: 2,160 mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Pegylated Liposomal Doxorubicin Hydrochloride; Initial disease status: Recurrent Disease; Days to treatment start: 622 days (1.7 years); Days to treatment end: 767 days (2.1 years); Number of cycles: 6; Treatment dose: 540 mg; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 65.6 years (23,960 days); Days to diagnosis: 544 days (1.5 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 544 days (1.5 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 544 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 544 days (1.5 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 886 days (2.4 years); Disease response: Tumor Free.
- Progression or recurrence: Yes; Progression or recurrence type: Distant; Evidence of progression type: Convincing Image Source; Timepoint: Post Initial Treatment.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-23-1030-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.5; Intermediate dimension: 0.8; Shortest dimension: 0.5.
  Slide TCGA-23-1030-01A-02-BS2: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 95; Percent normal cells: 5; Percent necrosis: 5; Percent stromal cells: 5.
  Slide TCGA-23-1030-01A-01-BS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 0.
- Sample TCGA-23-1030-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-23-1030-10C: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: Tumor free; History neoadjuvant treatment: No; Anatomic organ subdivision: Left; Method initial path diagnosis: Tumor resection; Lymphovascular invasion indicator: Yes.
- Drug treatment 1: Pharmaceutical therapy drug name: Doxil.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Xyotax; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Consolidation.
- Follow-up form: Treatment outcome first course: Complete Remission/Response; Tumor status: Tumor free.

The TCGA Pan-Cancer Clinical Data Resource (Liu et al., Cell 2018) lists this case as redacted by TCGA at the time of its curation; its follow-up endpoints are therefore not restated here.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-23-1030-01A-02D-0428-01): tumor purity 0.87, ploidy 2.87, whole-genome doublings 1.
